Gene-level copy-number profile of tumor specimen TCGA-05-5420-01A from TCGA case TCGA-05-5420, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 67.0 years (24,472 days).
Specimen TCGA-05-5420-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.d6d274a9-5a2e-46f3-9729-0d29cb218564.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-05-5420-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3618b45e-1a88-4578-a989-cdb690cb4432

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 8; copy number 1: 16,284; copy number 2: 38,978; copy number 3: 2,950; copy number 4: 1,073; copy number 5: 107; copy number 6: 380; copy number 7: 35.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-05-5420-01): tumor purity 0.25, ploidy 1.82, whole-genome doublings 0 (call status: maf_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 522 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:65,155,407–67,407,072, 46 genes, copy number 5: RPL31P41, LINC00251, PPIAP86, LINC01299, AC100814.1, Y_RNA, ARMC1, MTFR1, AC055822.1, PDE7A, AC100812.1, DNAJC5B, AC084082.1, TRIM55, CRH, LINC00967, AC009879.4, RRS1-AS1, RRS1, AC009879.2, AC009879.3, ADHFE1, AC009879.1, VXN, RNU6-1324P, MYBL1, VCPIP1, Y_RNA, C8orf44-SGK3, C8orf44, SGK3, PTTG3P, MCMDC2, SNHG6, SNORD87, TCF24, PPP1R42, AC110998.1, COPS5, CSPP1, RNA5SP268, AC087359.1, ARFGEF1, AC021321.2, AC021321.1, AC011037.1.
- chr8:79,259,402–80,613,826, 35 genes, copy number 6: AC138646.1, AC100870.1, RPL3P9, STMN2, AC016240.1, HEY1, LINC01607, AC036214.1, RNU7-85P, AC036214.4, MRPS28, AC036214.3, AC036214.2, AC009686.2, TPD52, AC009686.1, RN7SL41P, MIR5708, AC104212.3, AC034114.2, AC104212.2, AC104212.1, AC034114.1, RNU6-1213P, AC009812.1, Y_RNA, ZBTB10, AC009812.3, AC009812.4, RPSAP47, RNU7-174P, AC009812.2, RNU2-71P, SLC25A51P3, RN7SL107P.
- chr8:80,644,939–80,645,173, 1 gene, copy number 6: CKS1BP7.
- chr8:95,947,781–97,149,654, 17 genes, copy number 6: SRSF3P2, AC012339.1, GAPDHP30, AC007992.1, AP003465.2, GDF6, UQCRB, AP003465.1, MTERF3, PTDSS1, Y_RNA, AP003548.1, RNU6-1172P, SDC2, CPQ, AP003117.2, AP003117.1.
- chr8:122,414,332–123,737,402, 42 genes, copy number 6 (within-gene range 4–6): SMILR, LINC01151, AC108136.1, AC100872.1, AC100872.2, CDK5P1, AC016405.3, AC016405.2, ZHX2, AC016405.1, AC104316.2, AC104316.1, DERL1, TBC1D31, HMGB1P19, AC068228.3, FAM83A, U3, AC068228.1, AC068228.2, FAM83A-AS1, MIR4663, C8orf76, ZHX1-C8orf76, UBA52P5, ZHX1, RNU6-628P, AC018992.1, ATAD2, RNU6-875P, MIR548AA1, MIR548D1, DUTP2, IMPDH1P6, NTAQ1, U4, FBXO32, AC090193.1, RN7SKP155, AC135166.1, KLHL38, ANXA13.
- chr8:128,150,116–145,066,685, 320 genes, copy number 6–7 (broad region; genes not listed).
- chr22:20,602,595–21,551,461, 60 genes, copy number 5 (within-gene range 1–5): SMPD4P1, IGLL4P, SLC9A3P2, ABHD17AP4, POM121L4P, BCRP5, TMEM191A, PI4KA, SERPIND1, SNAP29, AC007308.1, CRKL, LINC01637, AIFM3, AC002470.2, AC002470.1, LZTR1, THAP7, THAP7-AS1, AC002472.2, TUBA3FP, P2RX6, AC002472.3, SLC7A4, AC002472.1, MIR649, P2RX6P, LRRC74B, TUBA3GP, AC002472.4, BCRP2, AP000550.1, POM121L7P, E2F6P2, FAM230B, AP000550.2, FAM247A, GGT2, AP000550.3, E2F6P3, POM121L8P, BCRP6, FAM230H, AP000552.2, PPP1R26P5, LINC01651, FAM246A, AP000552.1, Metazoa_SRP, RIMBP3B, RN7SKP63, AP000552.3, Metazoa_SRP, HIC2, Metazoa_SRP, TMEM191C, PI4KAP2, AP000557.1, RN7SKP221, RIMBP3C.
- chr22:21,555,138–21,555,457, 1 gene, copy number 5: Metazoa_SRP.

Autosomal genes at a single copy (total copy number 1): 13,871. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
